HCMI case HCM-CSHL-0664-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e681e4d0-b358-49ad-9ef8-88a32a6acb12

Demographics
Sex at birth: male; Year of birth: 1949; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.7; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 61.4 years (22,442 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N2b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: Yes; Vascular invasion type: Extramural.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 1,846 days (5.1 years); Days to treatment end: 2,131 days (5.8 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 1,846 days (5.1 years); Days to treatment end: 2,131 days (5.8 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,223 days (6.1 years); Days to treatment end: 2,404 days (6.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFOX; Days to treatment start: 2,223 days (6.1 years); Days to treatment end: 2,404 days (6.6 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab + Irinotecan; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 2,677 days (7.3 years); Days to treatment end: 2,738 days (7.5 years).
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 3,210 days (8.8 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 70.2 years (25,658 days); Days to diagnosis: 3,216 days (8.8 years).
   Pathology details: Vascular invasion present: No.

Follow-up (2 entries)
- Days to follow up: 3,733 days (10.2 years); Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 3,664.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- CEA: 2.66 ng/mL.
- CEA: 5.4 ng/mL.
- KRAS mutation, nos: Negative.
- MLH1 (IHC): Positive.
- MSH2 (IHC): Positive.
- MSH6 (IHC): Positive.
- PMS2 (IHC): Positive.
- Test (Microsatellite Analysis): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Diabetes, Type II.
- Timepoint category: Initial Diagnosis; Weight: 100 kg; Height: 170 cm; BMI: 35.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0664-C18-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0664-C18-06A-01-S1-HE: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 6.
  Slide HCM-CSHL-0664-C18-06A-01-S2-HE: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 7; Percent stromal cells: 13; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 5.
- Sample HCM-CSHL-0664-C18-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0664-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 20.
